Somatic mutation profile of tumor specimen TCGA-N9-A4Q4-01A (aliquot TCGA-N9-A4Q4-01A-11D-A28R-08) from TCGA case TCGA-N9-A4Q4, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC; Age at diagnosis: 61.8 years (22,575 days).
Specimen TCGA-N9-A4Q4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33d502e6-91b2-4508-addc-c209b09b070a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4Q4-10B (Blood Derived Normal), aliquot TCGA-N9-A4Q4-10B-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab3a521-86ea-4668-aa25-4566edc5b7f1

The open-access MAF lists 42 somatic variants for this specimen: 25 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 16, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHR | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs774992729; called by muse, mutect2, varscan2
- CD163L1 | c.1626C>A p.D542E | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as COSV58010454; called by muse, mutect2, varscan2
- MAP3K19 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs751721304, COSV59637434; called by muse, mutect2, varscan2
- NLGN4X | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338500760, COSV52004121, COSV99321427; called by muse, mutect2, varscan2
- NOTCH1 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53053354, COSV53078940; called by muse, mutect2, varscan2
- PPFIBP1 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.389); catalogued as rs765042927; called by muse, mutect2, varscan2
- PUM1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.691); catalogued as rs768025840, COSV57091749; called by muse, mutect2, varscan2
- SPIRE2 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs372155150; called by muse, mutect2, varscan2
- UTRN | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.218); catalogued as COSV100839980; called by muse, mutect2, varscan2
- ZNF780B | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs745803430, COSV55467844; called by muse, mutect2, varscan2
- ATP8B3 | c.998A>T p.N333I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- HIP1 | c.1420_1422del p.K474del | In Frame Del (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1800C>A p.N600K | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- IFNA16 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INPP5E | c.1200_1210del p.I401Gfs*25 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- LRRC8E | c.1121A>C p.D374A | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK8IP3 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- MGAM | c.231T>A p.D77E | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA2 | c.1502_1503dup p.Q502Dfs*21 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- SCRIB | c.3601G>T p.E1201* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- SH3TC2 | c.3289G>T p.G1097W | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX3 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.133); called by muse, mutect2
- SVIL | c.6587A>G p.Y2196C (on ENST00000355867 / NM_021738.3; = p.Y1770C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- USP7 | c.1511_1522del p.D504_R508delinsG | In Frame Del (DEL) | VAF 35/73 reads (48%) | called by mutect2, pindel, varscan2
- YARS1 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AKAP13 | c.5106A>G p.S1702= (on ENST00000394518 / NM_007200.5; = p.S1706= on NM_006738.6) | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- CASTOR1 | c.642G>A p.E214= | Silent (SNP) | VAF 37/39 reads (95%) | catalogued as rs1044650086; called by muse, mutect2, varscan2
- FRMPD4 | c.2940G>A p.P980= | Silent (SNP) | VAF 107/161 reads (66%) | catalogued as rs753070478; called by muse, mutect2, varscan2
- GRIK5 | c.2235C>A p.T745= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- HDAC5 | c.195C>T p.G65= | Silent (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.321G>A p.S107= | Silent (SNP) | VAF 87/158 reads (55%) | catalogued as rs370791268; called by muse, mutect2, varscan2
- LPAR4 | c.390C>A p.T130= | Silent (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- OR2M5 | c.495C>A p.S165= | Silent (SNP) | VAF 136/282 reads (48%) | called by muse, mutect2, varscan2
- OR5T1 | c.684C>A p.I228= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as COSV57301622; called by muse, mutect2, varscan2
- OR6K2 | c.429G>T p.L143= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV100656888; called by muse, mutect2, varscan2
- PKM | c.1417C>T p.L473= | Silent (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- PNMA3 | c.990G>T p.L330= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- SDC3 | c.882A>G p.P294= | Silent (SNP) | VAF 71/137 reads (52%) | called by muse, mutect2, varscan2
- SPHKAP | c.3024C>T p.D1008= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs200492792, COSV100764082; called by muse, mutect2, varscan2
- TAS2R41 | c.399C>G p.L133= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- WDR13 | c.450G>A p.G150= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.87T>C | RNA (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
